Somatic mutation profile of tumor specimen TCGA-61-1901-01A (aliquot TCGA-61-1901-01A-01W-0639-09) from TCGA case TCGA-61-1901, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 65.8 years (24,042 days).
Specimen TCGA-61-1901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6394f600-8f19-4a3b-b642-e22dd4789527.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1901-11A (Solid Tissue Normal), aliquot TCGA-61-1901-11A-01W-0640-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf380f16-9fe8-4599-8e20-0d3543ae3478

The open-access MAF lists 63 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Nonsense Mutation 4, Frame Shift Del 3, RNA 2, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024del p.R342Efs*3 | Frame Shift Del (DEL) | VAF 26/47 reads (55%) | catalogued as rs1131691022, CM004908, COSV52665487; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAM29 | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.214); catalogued as COSV100822151; called by muse, mutect2
- ADAM32 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as COSV65947950; called by muse, mutect2, varscan2
- ADCK2 | c.435del p.Y145* | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as COSV50780878; called by mutect2, pindel, varscan2
- AMPD2 | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1370996423, COSV56646830; called by muse, mutect2, varscan2
- CAPN7 | c.1575T>A p.D525E | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV53777267; called by muse, mutect2, varscan2
- CCL15 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs1202842463; called by muse, mutect2, varscan2
- CCNL2 | c.742G>C p.A248P | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101275702; called by muse, mutect2, varscan2
- CES5A | c.1497-1G>C p.X499_splice (on ENST00000290567 / NM_001143685.2; = p.X449_splice on NM_145024.3) | Splice Site (SNP) | VAF 351/591 reads (59%) | catalogued as COSV51864803; called by muse, mutect2, varscan2
- CNTNAP5 | c.1979G>A p.S660N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV70478013; called by muse, mutect2, varscan2
- DOCK10 | c.3749C>G p.T1250R | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV51359183, COSV51421058; called by muse, mutect2, varscan2
- DSEL | c.2245G>T p.V749L | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV100025897; called by muse, mutect2
- EXOC1 | c.2488A>C p.K830Q | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV62119479; called by muse, mutect2
- FAM3C | c.662G>A p.C221Y | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63435098; called by muse, mutect2, varscan2
- GABRA6 | c.718A>T p.M240L | Missense Mutation (SNP) | VAF 91/291 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV50878359; called by muse, mutect2, varscan2
- GUCY2F | c.1706A>T p.D569V | Missense Mutation (SNP) | VAF 274/750 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV54299683; called by muse, mutect2, varscan2
- ITGA2 | c.3116G>A p.S1039N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV56857447; called by mutect2, varscan2
- KCNK9 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV57279366; called by muse, mutect2, varscan2
- KIF21A | c.2200A>T p.R734* (on ENST00000361418 / NM_001378440.1; = p.R721* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 52/140 reads (37%) | catalogued as COSV62768626, COSV62773956; called by muse, mutect2, varscan2
- KIR2DL3 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 248/437 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780375565, COSV60896445; called by muse, varscan2
- LDLR | c.1550C>A p.S517Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52942186; called by muse, mutect2, varscan2
- LIPG | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs766943263, COSV99724601; called by muse, mutect2
- MAST2 | c.247G>T p.G83* | Nonsense Mutation (SNP) | VAF 9/156 reads (6%) | catalogued as COSV100788532; called by muse, mutect2
- OR2Z1 | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.314); catalogued as COSV60691940; called by muse, mutect2, varscan2
- OR4M1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 227/736 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.382); catalogued as COSV60060025; called by muse, mutect2, varscan2
- OSBPL3 | c.1679G>A p.C560Y | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57654237; called by muse, mutect2, varscan2
- PIWIL4 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs1045491294, COSV100133325; called by muse, mutect2
- PPP1R3A | c.1407dup p.H470Tfs*2 | Frame Shift Ins (INS) | VAF 118/306 reads (39%) | catalogued as rs770029712; called by mutect2, pindel, varscan2
- PTPRM | c.1988C>A p.A663E | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59849127; called by muse, mutect2, varscan2
- RARB | c.264C>A p.C88* (on ENST00000383772 / NM_001290216.2; = p.C81* on NM_000965.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 61/197 reads (31%) | catalogued as COSV58065761; called by muse, mutect2, varscan2
- RHOA | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs1250486455, COSV69041966; called by muse, mutect2, varscan2
- SLC12A5 | c.2804G>A p.R935H (on ENST00000454036 / NM_001134771.2; = p.R912H on NM_020708.5) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs764216462, COSV54790288, COSV99715954; called by muse, mutect2, varscan2
- SS18 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52260016; called by muse, mutect2, varscan2
- TAF1L | c.2083G>T p.G695* | Nonsense Mutation (SNP) | VAF 30/318 reads (9%) | catalogued as COSV99645090; called by muse, mutect2
- TECTA | c.2825G>A p.R942H | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.93); catalogued as rs774867371, COSV50692986; called by muse, mutect2, varscan2
- TEX15 | c.2751C>A p.S917R (on ENST00000256246; = p.S1300R on NM_001350162.2) | Missense Mutation (SNP) | VAF 92/259 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV56343369; called by muse, mutect2, varscan2
- TLR5 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV60558207; called by muse, mutect2, varscan2
- TMCO3 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV64807097; called by muse, mutect2, varscan2
- TMEM163 | c.859A>C p.M287L | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.07); catalogued as COSV56104593; called by muse, mutect2, varscan2
- TRNT1 | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs146717589, COSV52407691; called by muse, mutect2, varscan2
- TTN | c.11679A>C p.E3893D (on ENST00000591111; = p.E3847D on NM_003319.4) | Missense Mutation (SNP) | VAF 20/238 reads (8%) | catalogued as COSV100621903, COSV59923949; called by muse, mutect2
- USP33 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62468679; called by muse, mutect2, varscan2
- ZNF804B | c.2780T>A p.I927N | Missense Mutation (SNP) | VAF 30/711 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100304936; called by muse, mutect2
- ARHGAP28 | c.803C>A p.A268E (on ENST00000383472 / NM_001366230.1; = p.A109E on NM_001010000.3) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.104); called by muse, mutect2
- ASIC5 | c.54del p.I19* | Frame Shift Del (DEL) | VAF 52/97 reads (54%) | called by mutect2, pindel, varscan2
- IRF2 | c.541_549del p.S181_L183del | In Frame Del (DEL) | VAF 36/146 reads (25%) | called by mutect2, pindel, varscan2
- TRAV8-1 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 113/292 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CNNM4 | c.562C>T p.L188= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1268601646; called by mutect2, varscan2
- EFTUD2 | c.2664G>T p.R888= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as rs376156789; called by muse, mutect2, varscan2
- FRMPD4 | c.696C>G p.T232= | Silent (SNP) | VAF 72/226 reads (32%) | catalogued as COSV66212401; called by muse, mutect2, varscan2
- H1-2 | c.342G>T p.G114= | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as COSV59190019; called by muse, mutect2, varscan2
- KCNK6 | c.381G>T p.A127= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs144408830, COSV54579164; called by muse, mutect2, varscan2
- KIAA1549L | c.1416A>G p.A472= (on ENST00000321505; = p.A769= on NM_012194.3) | Silent (SNP) | VAF 138/389 reads (35%) | catalogued as COSV55770897; called by muse, mutect2, varscan2
- LRRC52 | c.771C>T p.A257= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as rs761775233, COSV54231247; called by muse, mutect2, varscan2
- NPEPPS | c.1089T>G p.V363= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV59101346; called by muse, mutect2, varscan2
- OR10P1 | c.843C>A p.V281= | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as COSV59006890; called by muse, varscan2
- OR2Z1 | c.490C>T p.L164= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs1264272223, COSV60691919, COSV60691944; called by muse, mutect2, varscan2
- OR5B2 | c.72C>A p.P24= | Silent (SNP) | VAF 133/425 reads (31%) | catalogued as COSV56907781; called by muse, mutect2, varscan2
- PCDHB4 | c.441G>A p.P147= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as rs782786858, COSV52020377; called by muse, mutect2, varscan2
- SVEP1 | c.1890C>T p.S630= | Silent (SNP) | VAF 24/292 reads (8%) | catalogued as rs761215073, COSV100238617; called by muse, mutect2
- ZNF20 | c.852G>A p.E284= | Silent (SNP) | VAF 140/345 reads (41%) | catalogued as COSV61998866; called by muse, mutect2, varscan2
- MIR1179 | n.10G>T | RNA (SNP) | VAF 57/101 reads (56%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2559C>A | RNA (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100832908, COSV64750036; called by muse, mutect2, varscan2
